Somatic mutation profile of tumor specimen TCGA-DU-5871-01A (aliquot TCGA-DU-5871-01A-12D-1705-08) from TCGA case TCGA-DU-5871, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 37.4 years (13,673 days).
Specimen TCGA-DU-5871-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bcfa0cc-d2d1-415f-9975-f94d5f40e5d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5871-10A (Blood Derived Normal), aliquot TCGA-DU-5871-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05789749-31b7-4260-847d-451ff08f8c69

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Intron 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 41/96 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 23/29 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADRB2 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs1209605702, COSV60005301; called by muse, mutect2, varscan2
- AMER1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV57660818; called by muse, mutect2, varscan2
- ATP11C | c.2256A>T p.L752F | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV59563916; called by muse, mutect2, varscan2
- BSG | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61076978; called by muse, mutect2, varscan2
- CCNQ | c.722A>T p.Y241F | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV52344355; called by muse, mutect2, varscan2
- CNTFR | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63633839; called by muse, mutect2, varscan2
- DQX1 | c.1565C>T p.T522M | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as rs201543859; called by muse, mutect2
- GIPC3 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); catalogued as rs766991127, COSV59259041; called by muse, mutect2, varscan2
- GPRIN3 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.08); catalogued as rs200774072, COSV60884925; called by muse, mutect2
- HMCN1 | c.13453C>T p.R4485W | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781672541, COSV54900578; called by muse, mutect2, varscan2
- IL23R | c.724T>C p.W242R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61374397; called by muse, mutect2, varscan2
- NOTCH3 | c.5491C>G p.L1831V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54634756; called by muse, mutect2, varscan2
- OR5M10 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV73242318, COSV99074300; called by muse, mutect2, varscan2
- PCM1 | c.509A>G p.Q170R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1455353376, COSV61516321; called by muse, mutect2, varscan2
- PIWIL2 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as rs199956088, COSV63251539; called by muse, mutect2, varscan2
- RPRD1B | c.815A>C p.K272T | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV65032917; called by muse, mutect2
- SLC16A12 | c.1551A>G p.*517Wext*46 | Nonstop Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV57949991; called by muse, mutect2, varscan2
- XYLT1 | c.1961C>T p.S654F | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54484587; called by muse, mutect2, varscan2
- ZNF77 | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58821876; called by muse, mutect2, varscan2
- ATRX | c.646_650del p.M216* | Frame Shift Del (DEL) | VAF 46/110 reads (42%) | called by pindel, varscan2
- IGHV3-20 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2
- EPG5 | c.6402A>G p.V2134= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as COSV56349659; called by muse, mutect2
- LILRB4 | c.1023C>T p.D341= (on ENST00000391733 / NM_001278428.3; = p.D340= on NM_001278426.3) | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as rs149652762; called by muse, mutect2, varscan2
- RXFP1 | c.660A>C p.G220= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV57049958; called by muse, mutect2, varscan2
- TSC22D4 | c.1062G>T p.R354= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV55724163, COSV55724816; called by muse, mutect2
- ITGA6 | c.3232-2280G>A | Intron (SNP) | VAF 32/99 reads (32%) | catalogued as COSV99904831; called by muse, mutect2, varscan2
